Somatic mutation profile of tumor specimen TCGA-W5-AA2U-01A (aliquot TCGA-W5-AA2U-01A-11D-A417-09) from TCGA case TCGA-W5-AA2U, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 78.2 years (28,552 days).
Specimen TCGA-W5-AA2U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0dbb2c09-c581-45fd-a403-6b9fbda5bba6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA2U-10A (Blood Derived Normal), aliquot TCGA-W5-AA2U-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69603314-1d7f-4690-b636-7af3facf4ef6

The open-access MAF lists 70 somatic variants for this specimen: 55 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 12, Nonsense Mutation 8, In Frame Del 3, Splice Site 2, RNA 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 31/98 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs776846119, COSV59205460, COSV59217320; called by muse, mutect2, varscan2
- AMBRA1 | c.2228A>G p.Q743R (on ENST00000458649 / NM_001367468.1; = p.Q653R on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs763567052; called by muse, mutect2, varscan2
- BCL3 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV99378073; called by muse, varscan2
- BCOR | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.873); catalogued as rs1475754838, COSV100654432; called by muse, mutect2
- COL6A6 | c.2071C>A p.Q691K | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs915186077; called by muse, mutect2, varscan2
- DISP1 | c.2652G>T p.E884D | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs138904556, COSV52660193; called by muse, mutect2, varscan2
- ERLEC1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs778793766, COSV51751194; called by muse, mutect2, varscan2
- FAM169A | c.1208C>A p.A403E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.037); catalogued as COSV65846999; called by muse, mutect2, varscan2
- GAL3ST2 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as rs769371859; called by muse, mutect2, varscan2
- GXYLT1 | c.473G>C p.S158T | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.216); catalogued as rs965079301; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99647355; called by muse, mutect2
- IGKV1-9 | c.179A>G p.Q60R | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as rs547763453; called by muse, mutect2, varscan2
- MAST4 | c.854C>G p.S285W (on ENST00000403625 / NM_001164664.2; = p.S96W on NM_015183.3) | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55141559; called by muse, mutect2, varscan2
- MYO5C | c.3388C>T p.H1130Y | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs754862405; called by muse, mutect2, varscan2
- PCDHA11 | c.2039G>A p.R680Q | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV100246847; called by muse, mutect2, varscan2
- PDE4A | c.962C>T p.P321L (on ENST00000380702 / NM_001111307.2; = p.P82L on NM_006202.3) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as rs200742358; called by muse, mutect2, varscan2
- PLEC | c.12727G>T p.E4243* (on ENST00000322810 / NM_201380.4; = p.E4133* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as COSV59660215; called by muse, mutect2, varscan2
- PREX2 | c.4700G>A p.R1567Q | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759522634, COSV55768758, COSV55780200; called by muse, mutect2, varscan2
- PTPRF | c.5081A>G p.Y1694C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1258470133, COSV63446899; called by muse, mutect2, varscan2
- ROR2 | c.1609G>A p.V537I | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs768540708; called by muse, varscan2
- SPNS1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs769292422, COSV57955435; called by muse, mutect2, varscan2
- SUPT20H | c.1726C>T p.P576S (on ENST00000350612 / NM_001014286.3; = p.P577S on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs1434558747; called by muse, mutect2, varscan2
- TLR1 | c.2121C>G p.C707W | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58303938; called by muse, mutect2, varscan2
- VGLL4 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 67/101 reads (66%) | SIFT tolerated (0.36); PolyPhen benign (0.043); catalogued as rs1490664912, COSV56075280, COSV56081089; called by muse, mutect2, varscan2
- ZNF449 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 31/73 reads (42%) | catalogued as COSV100202996; called by muse, mutect2, varscan2
- APP | c.1960C>G p.P654A | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLCN4 | c.1389+1G>A p.X463_splice | Splice Site (SNP) | VAF 8/48 reads (17%) | called by muse, varscan2
- CLIP4 | c.868_870del p.V290del | In Frame Del (DEL) | VAF 16/57 reads (28%) | called by pindel, varscan2
- DOCK9 | c.1435G>A p.E479K (on ENST00000376460 / NM_001366676.2; = p.E480K on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ELF4 | c.1522G>T p.G508* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2, varscan2
- EPHA7 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- FAM47C | c.2222A>T p.E741V | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.661); called by muse, mutect2
- GMPR | c.806T>A p.M269K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR50 | c.93_110del p.M31_V36del | In Frame Del (DEL) | VAF 9/122 reads (7%) | called by mutect2, pindel
- GYG2 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- IBSP | c.623_625del p.G208del | In Frame Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- IQGAP2 | c.3187A>T p.I1063F | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KTI12 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- MAGEA1 | c.483_484delinsC p.E161Dfs*15 | Frame Shift Del (DEL) | VAF 23/89 reads (26%) | called by pindel, varscan2*
- MAGEC1 | c.2539C>A p.P847T | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- NTRK3 | c.1121G>C p.G374A | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2J3 | c.788T>G p.L263R | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PPFIBP2 | c.364A>T p.I122L | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- PTPRC | c.2404-1G>T p.X802_splice | Splice Site (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2
- RAB11B | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPL36A | c.144T>G p.Y48* | Nonsense Mutation (SNP) | VAF 25/99 reads (25%) | called by muse, mutect2, varscan2
- RTL8C | c.122C>A p.P41Q | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- SCG5 | c.595A>T p.K199* (on ENST00000300175 / NM_001144757.2; = p.K198* on NM_003020.4) | Nonsense Mutation (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- SLC12A6 | c.170G>A p.S57N | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SRPX2 | c.931C>A p.Q311K | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.86); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TGM1 | c.683C>A p.S228* | Nonsense Mutation (SNP) | VAF 15/22 reads (68%) | called by muse, mutect2, varscan2
- THOC5 | c.1634C>A p.A545D | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- THOC5 | c.1633G>T p.A545S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- UBE4B | c.2400G>A p.W800* (on ENST00000343090 / NM_001105562.3; = p.W671* on NM_006048.5) | Nonsense Mutation (SNP) | VAF 33/51 reads (65%) | called by muse, mutect2, varscan2
- UBR1 | c.3940G>T p.D1314Y | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ABCA8 | c.3633A>C p.P1211= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99284985, COSV99285804; called by muse, mutect2, varscan2
- AC100868.1 | c.1588C>A p.R530= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs199706785, COSV51844467; called by muse, mutect2, varscan2
- APAF1 | c.2880T>C p.T960= (on ENST00000551964 / NM_181861.2; = p.T906= on NM_001160.3) | Silent (SNP) | VAF 17/26 reads (65%) | called by muse, mutect2, varscan2
- CDH26 | c.1206T>C p.I402= | Silent (SNP) | VAF 32/95 reads (34%) | called by muse, mutect2, varscan2
- EEFSEC | c.1296G>A p.R432= | Silent (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- GLRA2 | c.1119C>T p.S373= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as rs765737973, COSV54343961; called by muse, mutect2, varscan2
- GUCY2F | c.2139G>T p.T713= | Silent (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- LRP12 | c.603C>T p.A201= | Silent (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
- RIOK2 | c.1068G>T p.R356= | Silent (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- SRBD1 | c.1053C>T p.Y351= | Silent (SNP) | VAF 43/78 reads (55%) | called by muse, mutect2, varscan2
- UBTF | c.252A>C p.T84= | Silent (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- USP48 | c.996G>A p.G332= | Silent (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- BCAN | c.1942+27C>G | Intron (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100228372; called by muse, mutect2, varscan2
- CCNQP1 | n.586A>G | RNA (SNP) | VAF 29/73 reads (40%) | called by muse, mutect2, varscan2
- EI24P4 | n.1032T>A | RNA (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2
